Gene-level copy-number profile of tumor specimen MP2PRT-PATILY-TTM2-A from MP2PRT case MP2PRT-PATILY, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.1 years (2,246 days).
Specimen MP2PRT-PATILY-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4934e758-5027-4dc0-85fd-a07d544638f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATILY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/947fe5fe-7735-4a80-b812-5950b1dbba0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,697; copy number 2: 48,604; copy number 3: 1,088; copy number 4: 2,999; copy number 6: 2,443; copy number 7: 20; copy number 8: 31; copy number 12: 29.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,523 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–196,747,504, 1,389 genes, copy number 6–12 (broad region; genes not listed).
- chr1:196,819,731–248,937,043, 1,134 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
